TCGA case TCGA-AG-A026 — Rectum Adenocarcinoma (TCGA-READ)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Rectum; Tissue source site: Indivumed. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/31bd8589-378c-40e5-8b7f-3b4c81f304be

Demographics
Sex at birth: male; Country of residence at enrollment: Germany; Age at index: 66 years; Vital status: Dead; Days to death: 59 days.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C20; Tissue or organ of origin: Rectum, NOS; Site of resection or biopsy: Rectum, NOS; Classification of tumor: primary; Age at diagnosis: 66.8 years (24,413 days); Year of diagnosis: 2006; AJCC staging edition: 5th; AJCC pathologic T: T4; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage II; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R1.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 15; Lymphatic invasion present: Yes; Vascular invasion present: Yes.

Follow-up (1 entry)
- Days to follow up: 59 days; Disease response: With Tumor.

Molecular and laboratory tests
- CEA: 9.65 ng/mL.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-AG-A026-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 540 mg.
  Slide TCGA-AG-A026-01A-01-TS1: Section location: Top; Percent tumor cells: 10; Percent tumor nuclei: 20; Percent normal cells: 89; Percent necrosis: 1; Percent stromal cells: 0; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-AG-A026-01A-01-BS1: Section location: Bottom; Percent tumor cells: 75; Percent tumor nuclei: 80; Percent normal cells: 3; Percent necrosis: 2; Percent stromal cells: 20; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 3.
  Slide TCGA-AG-A026-01A-03-BS3: Section location: Bottom; Percent tumor cells: 25; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 60; Percent stromal cells: 15; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 1.
  Slide TCGA-AG-A026-01A-03-TS3: Section location: Top; Percent tumor cells: 68; Percent tumor nuclei: 75; Percent normal cells: 10; Percent necrosis: 2; Percent stromal cells: 20; Percent lymphocyte infiltration: 12; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 4.
- Sample TCGA-AG-A026-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-AG-A026-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Rectal Adenocarcinoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Lymph nodes examined: Yes; CEA level pretreatment: 9.65; Lymphovascular invasion indicator: Yes; KRAS gene analysis indicator: No; BRAF gene analysis indicator: No; History colon polyps: No; Mismatch rep proteins tested by IHC: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 59 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 59 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 59 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-AG-A026-01A-32D-A080-01): tumor purity 0.9, ploidy 3.02, whole-genome doublings 1.
